Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAG4, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAG4-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Summary pathology report

Left orchidectomy; nonseminoma (EC 80%, MT plus IT 15%, YST 4%, trophoblastic giant cells 1%); diameter 3 cm; tumor confined to testis; no angio-invasion; no invasion of rete testis.

Date of procurement (= date of orchidectomy):

pathologist

professor of pathology

ICD O-3
Mixed germ cell tumor
9085/3
Site @ Testis NOS C16.2.9
9/23/14

Source: NCI Genomic Data Commons file fb74a449-0681-4590-acaa-550efe1b421a (TCGA-2G-AAG4-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).